TCGA case TCGA-E6-A1LZ — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9205c164-7975-421a-90c3-edfe8def595c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 76.8 years (28,054 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; FIGO stage: Stage IA; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,406 days (6.6 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 5.
   Pathology details: Consistent pathology review: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 26.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 48 days; Treatment dose: 2,100 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 57 days; Days to treatment end: 162 days; Number of cycles: 6; Treatment dose: 2,735 mg; Prescribed dose: 467; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 57 days; Days to treatment end: 162 days; Number of cycles: 6; Treatment dose: 1,751 mg; Prescribed dose: 292; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (4 entries)
- Days to follow up: 1,289 days (3.5 years); Disease response: Tumor Free.
- Days to follow up: 1,471 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 2,406 days (6.6 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 4+; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E6-A1LZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 350 mg.
  Slide TCGA-E6-A1LZ-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-E6-A1LZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-E6-A1LZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Tumor resection; Surgical approach at diagnosis: open.
- Follow-up form 1: Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,406 days; disease-specific survival: no event (censored), 2,406 days; disease-free interval: no event (censored), 2,406 days; progression-free interval: no event (censored), 2,406 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E6-A1LZ-01A-11D-A141-01): tumor purity 0.56, ploidy 3.36, whole-genome doublings 1.
